Somatic mutation profile of tumor specimen ALCH-B26Q-TTP1-A (aliquot ALCH-B26Q-TTP1-A-1-0-D-A774-36) from ALCHEMIST case ALCH-B26Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.4 years (23,531 days).
Specimen ALCH-B26Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f567436e-67d8-4e23-8236-a7703da26bb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26Q-NB1-A (Blood Derived Normal), aliquot ALCH-B26Q-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2480acd7-ae47-4d51-aaae-9e4abbce9c6e

The open-access MAF lists 43 somatic variants for this specimen: 23 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 14, Intron 3, 3'UTR 2, Nonsense Mutation 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 82/630 reads (13%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- APEX1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 83/360 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs761265704, COSV51658240; called by muse, mutect2, varscan2
- BIRC6 | c.8668C>T p.R2890* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as rs777227964, COSV101428424; called by muse, mutect2, varscan2
- DDX54 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs201203830, COSV58372212; called by muse, mutect2
- EFEMP2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 32/560 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.845); catalogued as rs756337693, COSV57259538; called by muse, mutect2
- GDI1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 48/614 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557198952, COSV99341131; called by muse, mutect2
- GLT8D1 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1460270126; called by muse, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PKHD1 | c.3869G>A p.G1290D | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1265113009; called by muse, mutect2
- POTED | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.238); catalogued as rs1477872787, COSV55046477; called by muse, mutect2
- VPS13C | c.7274C>T p.T2425M (on ENST00000644861 / NM_020821.3; = p.T2382M on NM_017684.5) | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs547200034; called by muse, mutect2, varscan2
- EP300 | c.1253A>G p.K418R | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HK3 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- KCNJ8 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.2742A>T p.E914D (on ENST00000651989 / NM_001370785.2; = p.E881D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/482 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC7 | c.2743C>T p.H915Y (on ENST00000651989 / NM_001370785.2; = p.H882Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2
- MAGEB18 | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2
- NKX2-3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.773); called by muse, mutect2
- NRCAM | c.2536A>T p.M846L (on ENST00000379028 / NM_001371124.1; = p.M830L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH15 | c.5167C>A p.P1723T | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated, low confidence (0.95); called by muse, mutect2, varscan2
- SLC5A1 | c.998T>C p.M333T | Missense Mutation (SNP) | VAF 66/661 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR90 | c.175A>T p.K59* | Nonsense Mutation (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- WDR90 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.026); called by muse, mutect2
- ADGRG2 | c.2964C>T p.N988= (on ENST00000379869 / NM_001079858.3; = p.N985= on NM_005756.4) | Silent (SNP) | VAF 46/244 reads (19%) | catalogued as rs369376664, COSV61340860; called by muse, mutect2, varscan2
- BRAP | c.1629G>A p.Q543= | Silent (SNP) | VAF 83/381 reads (22%) | called by muse, mutect2, varscan2
- CAV3 | c.399C>T p.F133= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as rs769859957, COSV57479911; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CYP4F8 | c.1203C>A p.G401= | Silent (SNP) | VAF 45/313 reads (14%) | called by muse, mutect2, varscan2
- FRAS1 | c.783C>T p.C261= | Silent (SNP) | VAF 46/572 reads (8%) | catalogued as rs374802344; called by muse, mutect2
- LDLRAD2 | c.231C>T p.I77= | Silent (SNP) | VAF 24/396 reads (6%) | called by muse, mutect2
- MRGPRD | c.660C>T p.F220= | Silent (SNP) | VAF 30/199 reads (15%) | catalogued as rs1260902926; called by muse, mutect2, varscan2
- OR2T6 | c.450C>T p.F150= | Silent (SNP) | VAF 12/167 reads (7%) | catalogued as rs750148782, COSV63215990, COSV63216034; called by muse, mutect2
- PDZD2 | c.6408C>T p.V2136= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs576489739, COSV56859554; called by muse, mutect2, varscan2
- POM121L12 | c.423C>T p.I141= | Silent (SNP) | VAF 37/544 reads (7%) | catalogued as rs749775104, COSV68692276; called by muse, mutect2
- SLC6A18 | c.234C>T p.I78= | Silent (SNP) | VAF 70/429 reads (16%) | catalogued as rs141321317; called by muse, mutect2, varscan2
- SRA1 | c.120G>A p.Q40= | Silent (SNP) | VAF 37/440 reads (8%) | called by muse, mutect2
- TRPM2 | c.969C>T p.I323= | Silent (SNP) | VAF 76/565 reads (13%) | called by muse, mutect2, varscan2
- ZIC3 | c.612C>T p.S204= | Silent (SNP) | VAF 38/561 reads (7%) | called by muse, mutect2
- COQ7 | c.-22G>C | 5'UTR (SNP) | VAF 49/267 reads (18%) | called by muse, mutect2, varscan2
- CSF3R | c.*108C>T | 3'UTR (SNP) | VAF 61/295 reads (21%) | called by muse, mutect2, varscan2
- GID8 | c.*1055C>G | 3'UTR (SNP) | VAF 28/412 reads (7%) | called by muse, mutect2
- SLC5A2 | c.1022-45C>T | Intron (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- TPCN2 | c.174+9C>T | Intron (SNP) | VAF 29/225 reads (13%) | catalogued as rs1431586092; called by muse, mutect2, varscan2
- TUFM | c.923-20C>T | Intron (SNP) | VAF 64/659 reads (10%) | catalogued as rs750254304; called by muse, mutect2
